CCDI case PBCEKW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fbd0f20d-5777-4250-b473-134ddf79acf7

Demographics
Sex at birth: female.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 9.7 years (3,555 days).

Biospecimens (3 samples)
- Sample 0DQ2N3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ2ND: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQ2P0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
